Somatic mutation profile of tumor specimen TCGA-EO-A1Y7-01A (aliquot TCGA-EO-A1Y7-01A-11D-A159-09) from TCGA case TCGA-EO-A1Y7, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 65.9 years (24,085 days).
Specimen TCGA-EO-A1Y7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12dc2981-45df-4b1a-9532-d09b162e1794.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EO-A1Y7-10A (Blood Derived Normal), aliquot TCGA-EO-A1Y7-10A-01D-A159-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5d29c6e4-c5ba-41c4-9848-f3a4e6689080

The open-access MAF lists 60 somatic variants for this specimen: 42 protein-altering or splice-affecting, 17 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 17, Nonsense Mutation 5, Splice Region 1, Frame Shift Ins 1, Splice Site 1, In Frame Ins 1, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAT4 | c.11461C>T p.R3821* | Nonsense Mutation (SNP) | VAF 16/35 reads (46%) | catalogued as rs398122957, CM1311053, COSV58680175; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 86/92 reads (93%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 6/8 reads (75%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC11 | c.3239C>A p.A1080D | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as COSV100750479; called by muse, mutect2, varscan2
- ALPI | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1355266248, COSV99785652; called by muse, mutect2, varscan2
- BEND2 | c.1975G>A p.A659T | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.87); PolyPhen benign (0.006); catalogued as COSV101191735; called by muse, mutect2, varscan2
- BLCAP | c.28G>A p.V10I | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.766); catalogued as rs761861098, COSV99289949; called by muse, varscan2
- BTAF1 | c.3620C>G p.T1207R | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99794796, COSV99794804; called by muse, mutect2, varscan2
- C1QB | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.122); catalogued as COSV59245697; called by muse, mutect2, varscan2
- CCDC65 | c.547A>G p.I183V | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV99872657; called by muse, mutect2, varscan2
- CGB8 | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV100031899; called by muse, mutect2, varscan2
- CHD8 | c.460C>T p.Q154* | Nonsense Mutation (SNP) | VAF 33/71 reads (46%) | catalogued as rs1555318635, COSV101303026; called by muse, mutect2, varscan2
- CUX1 | c.3305C>A p.P1102H | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV99470236; called by muse, mutect2, varscan2
- DAB1 | c.602T>C p.I201T | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.632); catalogued as COSV100139250; called by muse, mutect2, varscan2
- DMD | c.6742G>T p.E2248* | Nonsense Mutation (SNP) | VAF 10/31 reads (32%) | catalogued as CM070894, COSV100625711; called by muse, mutect2, varscan2
- DPYSL2 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 19/24 reads (79%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1267866029, COSV60784916; called by muse, mutect2, varscan2
- ERAS | c.562G>A p.V188M | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs868935025, COSV54432482; called by muse, mutect2, varscan2
- ERBB3 | c.1009G>A p.G337R | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); catalogued as COSV57248420, COSV57263171; called by muse, mutect2, varscan2
- GBP1 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 72/174 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs149277121; called by muse, mutect2, varscan2
- GREB1 | c.4583G>A p.S1528N | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV52182322; called by muse, mutect2, varscan2
- HMMR | c.1291A>C p.S431R | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as COSV100700957; called by muse, mutect2, varscan2
- ITGAV | c.2784C>G p.Y928* | Nonsense Mutation (SNP) | VAF 27/90 reads (30%) | catalogued as COSV53714130, COSV53719622, COSV99654145; called by muse, mutect2, varscan2
- JPH3 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 46/72 reads (64%) | SIFT deleterious (0.05); PolyPhen benign (0.223); catalogued as rs538808011, COSV52464528, COSV52464997; called by muse, mutect2, varscan2
- KRT78 | c.100G>A p.G34S | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.855); catalogued as COSV100467080; called by muse, mutect2, varscan2
- MDN1 | c.3233A>C p.Y1078S | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.19); catalogued as COSV101020702; called by muse, mutect2, varscan2
- MED12L | c.5159C>T p.P1720L | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV99851272; called by muse, mutect2, varscan2
- MICAL3 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 28/28 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs763498380, COSV52902147; called by muse, mutect2, varscan2
- MMP9 | c.1531C>T p.P511S | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100812332; called by muse, mutect2, varscan2
- OR2C3 | c.670C>T p.R224W | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs1195741075, COSV63574692, COSV63576737; called by muse, mutect2, varscan2
- PIK3R1 | c.1387_1392dup p.Y463_D464dup (on ENST00000521381 / NM_181523.3; = p.Y193_D194dup on NM_181504.4) | In Frame Ins (INS) | VAF 5/36 reads (14%) | catalogued as COSV57138010; called by mutect2, pindel, varscan2
- PKD1 | c.1560C>A p.D520E | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); catalogued as rs1427908066, COSV99237038; called by muse, mutect2, varscan2
- RAP1A | c.331A>G p.M111V | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.297); catalogued as rs374282055; called by muse, mutect2, varscan2
- RXFP1 | c.536+1G>A p.X179_splice | Splice Site (SNP) | VAF 8/21 reads (38%) | catalogued as COSV100313505; called by muse, mutect2, varscan2
- SASH1 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 20/24 reads (83%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.165); catalogued as rs772638237, COSV100820858, COSV66560859; called by muse, mutect2, varscan2
- SGIP1 | c.471G>A p.P157= | Splice Region (SNP) | VAF 32/64 reads (50%) | catalogued as rs757052098, COSV52772567; called by muse, mutect2, varscan2
- SLC16A10 | c.755G>T p.R252L | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV100920803; called by muse, mutect2
- ZFPM2 | c.2915T>C p.I972T | Missense Mutation (SNP) | VAF 48/60 reads (80%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as rs1256654784, COSV101022941; called by muse, mutect2, varscan2
- ZNF462 | c.6319G>A p.G2107R | Missense Mutation (SNP) | VAF 19/26 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1483171063, COSV52933405, COSV99472856; called by muse, mutect2, varscan2
- AIDA | c.751dup p.R251Kfs*15 | Frame Shift Ins (INS) | VAF 15/39 reads (38%) | called by mutect2, varscan2
- DYNC1H1 | c.11249_11251del p.L3750del | In Frame Del (DEL) | VAF 8/28 reads (29%) | called by pindel, varscan2
- ELOA3B | c.880C>A p.Q294K | Missense Mutation (SNP) | VAF 22/460 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.972); called by muse, mutect2
- ZNF292 | c.707G>T p.C236F | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2
- BCAR1 | c.300G>A p.T100= | Silent (SNP) | VAF 42/194 reads (22%) | catalogued as rs767982253, COSV99365832; called by muse, mutect2, varscan2
- CEBPE | c.270C>T p.Y90= | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as rs1038668199, COSV99247296; called by muse, mutect2, varscan2
- EID2B | c.6G>C p.A2= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV100410968; called by muse, mutect2, varscan2
- ELAPOR2 | c.1971C>T p.C657= (on ENST00000450689 / NM_001142749.3; = p.C490= on NM_152748.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 48/95 reads (51%) | catalogued as rs751578906, COSV51889281; called by muse, mutect2, varscan2
- GEMIN2 | c.555A>G p.R185= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as COSV99158016; called by muse, mutect2, varscan2
- ITFG2 | c.618G>A p.A206= | Silent (SNP) | VAF 30/74 reads (41%) | catalogued as rs373908169, COSV57389115; called by muse, mutect2, varscan2
- KMT2D | c.4311C>T p.S1437= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs754428432, COSV99976973; called by muse, mutect2, varscan2
- KRTAP21-2 | c.63C>T p.S21= | Silent (SNP) | VAF 43/95 reads (45%) | catalogued as rs781308785, COSV100441253, COSV61684214; called by muse, mutect2, varscan2
- NAP1L2 | c.873C>T p.F291= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as COSV100999175; called by muse, mutect2, varscan2
- NPHS1 | c.2256C>T p.N752= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as rs530683414, COSV100799567; called by muse, mutect2, varscan2
- PCIF1 | c.363C>T p.S121= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs1333820711, COSV100975959; called by muse, mutect2, varscan2
- PPARD | c.1128C>A p.T376= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as COSV100282912; called by muse, mutect2, varscan2
- SLC12A3 | c.1593C>A p.I531= | Silent (SNP) | VAF 61/125 reads (49%) | catalogued as COSV52636878, COSV99343758; called by muse, mutect2, varscan2
- SLITRK4 | c.1596A>C p.P532= | Silent (SNP) | VAF 4/59 reads (7%) | catalogued as COSV100567108; called by muse, mutect2
- TWNK | c.1518C>T p.Y506= | Silent (SNP) | VAF 17/67 reads (25%) | catalogued as rs979193812, COSV52970253; called by muse, mutect2, varscan2
- XIRP2 | c.6033T>G p.T2011= (on ENST00000628543; = p.T2186= on NM_152381.6) | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV54708469; called by muse, mutect2, varscan2
- ZFHX4 | c.8697C>T p.S2899= | Silent (SNP) | VAF 3/33 reads (9%) | catalogued as rs1484307374, COSV99255177; called by muse, mutect2
- ANKEF1 | c.*1G>C | 3'UTR (SNP) | VAF 14/32 reads (44%) | catalogued as COSV101000970; called by muse, mutect2, varscan2
